Somatic mutation profile of tumor specimen TCGA-QR-A6H5-01A (aliquot TCGA-QR-A6H5-01A-11D-A35D-08) from TCGA case TCGA-QR-A6H5, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 30.1 years (10,987 days).
Specimen TCGA-QR-A6H5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65574dcf-973e-4bf0-9d10-bc88472aa437.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6H5-10A (Blood Derived Normal), aliquot TCGA-QR-A6H5-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0eefb1aa-2b7c-43ab-9077-78cfddc3dc57

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs730882035, CM951290, CM961431, COSV104374399, COSV56542648, COSV56545213, COSV56545244; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALMS1 | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV52511040; called by muse, mutect2, varscan2
- C20orf85 | c.170A>G p.D57G | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs532382153; called by muse, mutect2, varscan2
- FEM1B | c.249-2A>G p.X83_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as rs111343207; called by muse, mutect2, varscan2
- CXADR | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RTL1 | c.2896C>T p.L966F | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.438); called by muse, mutect2
